CCDI case PBBZEJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/9ae03cb3-df84-4cde-97ec-9d1faafb7b42

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.4 years (511 days).

Biospecimens (3 samples)
- Sample 0DLJWE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLJWM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLJX7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
